Surgical pathology report (de-identified scan), TCGA case TCGA-M7-A721, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of North Carolina, specimen TCGA-M7-A721-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Prostate, robotic prostatectomy

Tumor histologic type: Prostatic adenocarcinoma

Tumor grade (Gleason system): 7 (3+4)

Approximate percentage of prostate involved by tumor: 5%

Extent of tumor:

Location of tumor involvement in prostate: Right apex, mid, and base of prostate; Left apex and mid-prostate

Confinement/non-confinement of tumor within the prostatic capsule: Confined

Lymphovascular space invasion: Not identified

Seminal vesicles (invasion of muscular wall required): No involvement

Histologic assessment of surgical margins: Focally positive; < 1 mm involving right apex (A1, A13) and apical/mid right prostate

Other significant findings:

- Focal glandular atrophy
- Benign prostatic hypertrophy

Lymph nodes: None submitted

AJCC Staging:

pT2C

pNX

This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

Clinical History:

year-old male with prostate cancer.

CCCF ICD-O-3
Adenocarcinoma, acinar
path 8/14/13
Adenocarcinoma NOS
8/14/13
Site Prostate NOS
C61.9
JW 8/12/13

[page 2 of 2]
Gross Description:

Specimen fixation: formalin

Type of specimen(s) received: robotic assisted laparoscopic prostatectomy

Size of specimen: 4.2 x 4.0 x 3.5 cm

Weight of specimen: 37 grams

Orientation: Right=blue, left=black, apex=yellow, base/bladder neck=red

Size and description of other organs or structures: The right seminal vesicle measures 4.5 x 2.1 x 0.5 cm. The right vas deferens measures 2.6 x 0.4 x 0.3 cm. The left seminal vesicle measures 3.7 x 2.2 x 0.5 cm. The left vas deferens measures 2.9 x 0.7 x 0.2 cm.

Gross description of prostate: The prostate consists of tan/white fibrous tissue with yellowish discoloration present in focal areas throughout the prostate.

Digital photograph taken: not taken

Block summary:

A1,A2 - perpendicular sections of right apex
A3,A4 - perpendicular sections of left apex
A5,A6 - perpendicular sections of right bladder neck margin
A7,A8 - perpendicular sections of left bladder neck margin
A9 - right seminal vesicle at level of prostate
A10 - left seminal vesicle at level of prostate
A11 - right vas deferens margin
A12 - left vas deferens margin
A13-A19 - right prostate, from apex to base, respectively
A20-A26 - left prostate, from apex to base, respectively

Criteria	hw 7/26/13	Yes	No
H&PAA Discrepancy			✓

Source: NCI Genomic Data Commons file 61c8d0f3-0f6b-468e-95f4-c4ddd8ffd84d (TCGA-M7-A721.357FE07A-B561-44BF-B59B-811F77C1F634.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).